Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8216, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8216-01A (Primary Tumor).

SPECIMEN INF

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Radical prostatectomy:
Carcinoma.

Tumor Characteristics:

1. Histologic type: Adenocarcinoma, usual type.
2. Prostate size: 54 grams, 5.6 x 4.0 x 3.0 cm.
3. Tumor quantitation: Approximately 10% of gland volume.
4. Gleason grade:
- a. Primary pattern: 4/5.
- b. Secondary pattern: 3/5 with tertiary pattern of 5/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Focal, right posterior base area.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Present.
8. High grade PIN: Present.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Margins uninvolved.

Lymph Node Status (utilizing specimen B):

1. Total number of lymph nodes received: 3.
2. Total number of lymph nodes containing metastatic carcinoma: None (0/3).

Other:

1. Other significant findings: None.
2. pTNM stage: pT3a,N0.

B. Right pelvic lymph nodes:

Three benign hyperplastic lymph nodes (0/3).

Electronic Signature: [REDACTED]

COMMENTS:

Consultant Dr.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Prostate cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Prostate
- B. Right pelvic lymph nodes

SPECIMEN DATA

GROSS DESCRIPTION:

Specimen is received in two formalin filled containers labeled with the patient's name

A. Additionally labeled prostate and contains a 54 gram, 5.6 x 4.0 x 3.0 cm prostate received with attached bilateral adnexa having overall dimensions of 5.0 x 4.5 x 1.2 cm. Specimen is inked as follows: right side blue and left side black. Prostatic capsule is pink-tan and shaggy. The base and apical margins are coned and serially sectioned. The remainder of gland is serially sectioned from apex to base to reveal a pink-tan focally cystic cut surface with diffuse periurethral nodularity. A discrete mass is not identified. Representative sections are submitted in cassettes A1-18 labeled designated as follows: 1-right prostate/seminal vesicle at level of junction; 2-left prostate/seminal vesicle at level of junction; 3-4-apical margin, perpendicular; 5-6-base margin, perpendicular; 7-9-right anterior, apex to base; 10-12-right posterior, apex to base; 13-15-left anterior, apex to base;

16-18-left posterior, apex to base. Additionally, a yellow green and blue cassette are submitted for

research each labeled [REDACTED]

B. Additionally labeled right pelvic lymph nodes and contains a 3.8 x 2.7 x 1.5 cm yellow-tan fibrofatty soft tissue. On palpation, three firm fatty possible lymph nodes are identified ranging from 0.7 up to 3.0 cm in greatest dimension. They are entirely submitted in cassettes B1-4 labeled designated as follows: B1-two whole possible lymph nodes; B2-4-one whole possible trisected lymph node.

Source: NCI Genomic Data Commons file d44c86b3-4d3f-4db1-ae5e-ef2598fb1e69 (TCGA-HC-8216.CD881D57-9CCB-4984-8C37-B3DDE9189814.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).